Somatic mutation profile of tumor specimen C3L-06063-54 (aliquot CPT0326000002) from CPTAC case C3L-06063, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 50.0 years (18,260 days).
Specimen C3L-06063-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6b5cb88-a6b6-443c-816b-70d95108c732.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06063-51 (Buccal Cell Normal), aliquot CPT0326100003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2145ddf-5979-46fa-8d66-260e5a9cf9b5

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 81/190 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 25/65 reads (38%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACTR3B | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1162816026, COSV55447175, COSV99753974; called by muse, mutect2, varscan2
- GNAS | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 134/281 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); catalogued as rs751302306; called by muse, mutect2, varscan2
- KDELR2 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 158/285 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51727438; called by muse, mutect2, varscan2
- MAPK3 | c.173C>A p.S58* | Nonsense Mutation (SNP) | VAF 173/364 reads (48%) | catalogued as rs1370684329; called by muse, mutect2, varscan2
- RPH3A | c.1717C>T p.R573C (on ENST00000389385 / NM_001143854.2; = p.R569C on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763849876, COSV66992196; called by muse, mutect2
- ZZEF1 | c.5624C>T p.T1875M | Missense Mutation (SNP) | VAF 183/504 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1187816567, COSV101067326; called by muse, mutect2, varscan2
- CABIN1 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 208/486 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- DRC1 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.247); called by muse, mutect2
- OPA1 | c.2761C>T p.H921Y (on ENST00000361510 / NM_130837.3; = p.H866Y on NM_015560.3) | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- RNF6 | c.1330A>G p.T444A | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- VAPB | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 153/381 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WT1 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 103/296 reads (35%) | called by muse, mutect2, varscan2
- ITGA11 | c.9G>A p.L3= | Silent (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- PCDHB6 | c.786C>T p.T262= | Silent (SNP) | VAF 127/334 reads (38%) | called by muse, mutect2, varscan2
- TDRD12 | c.3243C>T p.H1081= (on ENST00000444215; = p.H1086= on NM_001366102.1) | Silent (SNP) | VAF 44/108 reads (41%) | called by muse, mutect2, varscan2
- TXNDC2 | c.693C>T p.P231= (on ENST00000306084 / NM_001098529.2; = p.P164= on NM_032243.6) | Silent (SNP) | VAF 109/180 reads (61%) | called by muse, mutect2, varscan2
